Somatic mutation profile of tumor specimen ALCH-B27D-TTP1-A (aliquot ALCH-B27D-TTP1-A-1-0-D-A774-36) from ALCHEMIST case ALCH-B27D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.8 years (25,842 days).
Specimen ALCH-B27D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c083e730-1bb6-4572-80ac-82259748dd91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27D-NB1-A (Blood Derived Normal), aliquot ALCH-B27D-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30e20a64-2324-4edd-9dba-6ccecfbcfd90

The open-access MAF lists 467 somatic variants for this specimen: 328 protein-altering or splice-affecting, 83 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 288, Silent 83, Nonsense Mutation 23, Intron 22, RNA 13, Splice Site 8, 3'UTR 7, 5'UTR 6, 5'Flank 5, Frame Shift Del 4, Splice Region 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2
- ADAP1 | c.470A>T p.E157V | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs751142364; called by muse, mutect2, varscan2
- AMOTL2 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs778410312; called by muse, mutect2, varscan2
- ANK2 | c.3863G>T p.C1288F | Missense Mutation (SNP) | VAF 59/380 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171500202; called by muse, mutect2, varscan2
- ANXA6 | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs763145975; called by muse, mutect2, varscan2
- ARHGAP28 | c.1462C>T p.H488Y (on ENST00000383472 / NM_001366230.1; = p.H329Y on NM_001010000.3) | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.129); catalogued as COSV51646532; called by muse, mutect2, varscan2
- ASPM | c.8064G>T p.M2688I | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.176); catalogued as COSV99659307; called by mutect2, varscan2
- BICD1 | c.2000A>G p.K667R | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs747373437; called by muse, mutect2, varscan2
- BICDL2 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); catalogued as COSV54155393; called by muse, mutect2, varscan2
- C11orf58 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV57178124; called by muse, mutect2, varscan2
- C16orf72 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV59916415; called by muse, mutect2, varscan2
- C19orf81 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); catalogued as COSV53262596; called by muse, mutect2, varscan2
- CD1C | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV63807867; called by muse, mutect2, varscan2
- CD96 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1223285436; called by muse, mutect2, varscan2
- CDC14C | c.1626G>A p.W542* (on ENST00000428251; = p.W435* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 25/281 reads (9%) | catalogued as rs1297158858; called by muse, mutect2
- CDH10 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV100051848; called by muse, mutect2
- CDH19 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as rs768655385; called by muse, mutect2, varscan2
- CDH20 | c.2104C>G p.L702V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.155); catalogued as COSV53012764; called by muse, mutect2, varscan2
- CECR2 | c.3022G>T p.D1008Y (on ENST00000342247 / NM_001290047.2; = p.D824Y on NM_001290046.1) | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV52843252; called by muse, mutect2, varscan2
- CFAP54 | c.3005G>C p.G1002A | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1282343821; called by muse, mutect2
- CLSPN | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs1328436364; called by muse, varscan2
- CMYA5 | c.7910C>T p.P2637L | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs759553376; called by muse, mutect2, varscan2
- COL4A4 | c.1618C>A p.L540I | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV61631372; called by muse, varscan2
- COL6A5 | c.2127G>C p.K709N | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1403349461; called by muse, varscan2
- CPB2 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV51676981; called by muse, varscan2
- CRACD | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1379374919; called by muse, mutect2, varscan2
- CRACD | c.2629G>T p.D877Y | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51716899; called by muse, mutect2, varscan2
- CRYBG3 | c.8368G>A p.V2790I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.319); catalogued as COSV51716738; called by muse, mutect2, varscan2
- CSF2RB | c.286T>G p.C96G | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53261168; called by muse, mutect2
- CTNNBIP1 | c.53A>C p.Q18P | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1343663953; called by muse, mutect2, varscan2
- DMP1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as rs773290498; called by muse, mutect2, varscan2
- EHD2 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54407479; called by muse, mutect2, varscan2
- EML1 | c.1732G>T p.V578F | Missense Mutation (SNP) | VAF 53/325 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs376629514, COSV99214370, COSV99215314; called by muse, mutect2, varscan2
- EP300 | c.4154G>T p.C1385F | Missense Mutation (SNP) | VAF 69/459 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325300, COSV54328894; called by muse, mutect2, varscan2
- ERVV-2 | c.1382T>G p.L461R | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV74153553; called by muse, mutect2, varscan2
- F8 | c.3980C>T p.T1327M | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs200520711, COSV64274888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM20C | c.1646G>C p.R549P | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58235070; called by muse, mutect2
- FAM47C | c.2707C>A p.L903I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1569417557; called by muse, mutect2
- FLG | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 51/462 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV100911668; called by muse, mutect2, varscan2
- FN1 | c.3348G>A p.K1116= | Splice Region (SNP) | VAF 38/486 reads (8%) | catalogued as COSV60559064; called by muse, mutect2
- GASK1B | c.550C>G p.R184G | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV56705880; called by muse, mutect2, varscan2
- GPRC6A | c.2692C>A p.L898I | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); catalogued as COSV59952665; called by muse, mutect2, varscan2
- GRID2 | c.1995C>A p.I665= | Splice Region (SNP) | VAF 12/58 reads (21%) | catalogued as COSV56284085; called by mutect2, varscan2
- HOXB2 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV57488529; called by muse, mutect2, varscan2
- HOXB3 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs768811869; called by muse, mutect2, varscan2
- IFT172 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs746834072, COSV53133695; called by muse, mutect2
- ISM1 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 86/475 reads (18%) | catalogued as rs199544117, COSV104390494; called by muse, varscan2
- ITIH2 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs139781584; called by muse, mutect2, varscan2
- KCTD9 | c.695G>C p.R232P | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55339708; called by muse, mutect2, varscan2
- KIF4A | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs906342959; called by muse, mutect2, varscan2
- LRRCC1 | c.2405G>C p.R802P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64485549; called by mutect2, varscan2
- MAGI1 | c.2944G>A p.G982S (on ENST00000402939 / NM_001033057.2; = p.G1010S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58346541; called by muse, mutect2, varscan2
- MAPK9 | c.786C>G p.N262K | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs768944763; called by muse, mutect2, varscan2
- MCC | c.1663A>G p.S555G | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs746064641; called by muse, mutect2, varscan2
- MINDY3 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.981); catalogued as rs759060381; called by muse, mutect2, varscan2
- MS4A14 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1294164681; called by muse, mutect2, varscan2
- MUC16 | c.28001C>A p.P9334Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as COSV67448746; called by muse, mutect2, varscan2
- MUC16 | c.16742C>A p.P5581H | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.526); catalogued as COSV67466758; called by muse, mutect2, varscan2
- MYH2 | c.5183G>A p.S1728N | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV55431792; called by muse, mutect2, varscan2
- MYH7 | c.3035C>A p.A1012D | Missense Mutation (SNP) | VAF 92/347 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs779973529; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYLK | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV60604134; called by muse, mutect2, varscan2
- NISCH | c.4429G>T p.E1477* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV58736043; called by muse, mutect2, varscan2
- NKX3-1 | c.538A>T p.K180* | Nonsense Mutation (SNP) | VAF 30/201 reads (15%) | catalogued as COSV66512071; called by muse, mutect2, varscan2
- NPIPB15 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 53/962 reads (6%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as rs543291877; called by muse, mutect2
- OR10G7 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57867872; called by muse, mutect2
- OR2T6 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs760588497, COSV63216564, COSV63216571; called by muse, mutect2, varscan2
- P2RY2 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60775547; called by muse, mutect2, varscan2
- PAX8 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs868126291; called by muse, mutect2
- PCDHB8 | c.1065C>A p.S355R | Missense Mutation (SNP) | VAF 38/646 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); catalogued as COSV50792819; called by muse, mutect2
- PIK3R2 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99717629; called by muse, mutect2, varscan2
- PKLR | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs185753709, CM981580, COSV61361211; called by muse, mutect2, varscan2
- PRR23C | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.082); catalogued as COSV101356427, COSV68826902; called by muse, mutect2, varscan2
- PRSS56 | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs552334838; called by muse, mutect2, varscan2
- PTPN18 | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV51559755; called by muse, mutect2
- RAB1A | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1443212461; called by muse, mutect2
- RABIF | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs1221106452; called by muse, mutect2, varscan2
- RASSF6 | c.330G>T p.K110N (on ENST00000342081 / NM_201431.2; = p.K78N on NM_177532.5) | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs1416760554; called by muse, mutect2, varscan2
- RGS18 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs757036248, COSV66507172; called by muse, mutect2
- RIMS2 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68113118; called by muse, mutect2
- RPS7 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV59232883; called by muse, mutect2
- RTEL1 | c.3445C>A p.Q1149K | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); catalogued as CD1511699; called by muse, mutect2, varscan2
- RTL8B | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV66954424; called by muse, mutect2, varscan2
- RTN1 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs552526309; called by muse, mutect2, varscan2
- RYR3 | c.7538G>T p.C2513F (on ENST00000389232; = p.C2514F on NM_001036.6) | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1477823780; called by muse, mutect2
- SCARA5 | c.1237C>A p.R413S | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV61570744; called by muse, mutect2, varscan2
- SEPTIN9 | c.802C>T p.R268W (on ENST00000427177 / NM_001113491.2; = p.R250W on NM_006640.4) | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs762063100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGPP2 | c.379-1G>T p.X127_splice | Splice Site (SNP) | VAF 15/132 reads (11%) | catalogued as rs761393506; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-1G>T p.X622_splice (on ENST00000540229 / NM_001371097.1; = p.X561_splice on NM_001009562.4) | Splice Site (SNP) | VAF 22/157 reads (14%) | catalogued as COSV101043800; called by muse, varscan2
- SMPD4 | c.2458G>T p.V820F (on ENST00000409031 / NM_017951.4; = p.V791F on NM_017751.4) | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1228974334; called by muse, mutect2
- SPAM1 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.055); catalogued as COSV56142846; called by muse, mutect2, varscan2
- SYNE1 | c.1669G>T p.E557* (on ENST00000367255 / NM_182961.4; = p.E564* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as COSV54974428, COSV54981787; called by muse, mutect2, varscan2
- TAF1L | c.2128A>T p.M710L | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs758103741; called by muse, mutect2, varscan2
- TARM1 | c.766G>T p.G256* (on ENST00000616041 / NM_001330650.1; = p.G248* on NM_001135686.3) | Nonsense Mutation (SNP) | VAF 16/282 reads (6%) | catalogued as COSV71524758; called by muse, mutect2
- TBC1D9 | c.1964A>T p.D655V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs986900968; called by muse, mutect2
- TGM5 | c.1321A>G p.T441A (on ENST00000220420 / NM_201631.4; = p.T359A on NM_004245.4) | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55011365; called by muse, mutect2, varscan2
- TMEM50B | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.291); catalogued as COSV101336638; called by muse, mutect2, varscan2
- UGT2B11 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749630839; called by muse, varscan2
- VENTX | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV58084587; called by muse, mutect2, varscan2
- VMO1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1380045536; called by muse, mutect2, varscan2
- VPS13B | c.9616G>A p.V3206I | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs904676214; called by muse, mutect2, varscan2
- VPS35L | c.1091C>A p.T364K | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs200808620; called by muse, mutect2, varscan2
- WT1 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 59/463 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as CM087007, CM1314670, COSV60071956; called by muse, mutect2, varscan2
- WT1 | c.1272C>A p.D424E | Missense Mutation (SNP) | VAF 60/467 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as COSV60084318; called by muse, mutect2, varscan2
- XKR3 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV58884635; called by muse, mutect2, varscan2
- ZFHX4 | c.2288A>G p.Q763R | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as rs949471392; called by muse, mutect2, varscan2
- ZFHX4 | c.4174C>A p.R1392S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768206311, COSV51500440; called by muse, mutect2, varscan2
- ZFHX4 | c.10102G>T p.E3368* | Nonsense Mutation (SNP) | VAF 29/165 reads (18%) | catalogued as COSV50584971; called by muse, mutect2, varscan2
- ZNF226 | c.2197G>T p.G733C | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56198118; called by muse, varscan2
- ZNF267 | c.1733G>A p.C578Y | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1316965143; called by muse, mutect2
- ZNF521 | c.2548C>A p.Q850K | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV64127257; called by muse, mutect2, varscan2
- ZNF543 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs34884181; called by muse, mutect2
- ABCB7 | c.2123A>C p.Q708P (on ENST00000373394 / NM_001271696.3; = p.Q709P on NM_004299.6) | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCG5 | c.142A>T p.S48C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ADAMTS12 | c.2795C>A p.P932H | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS19 | c.3177del p.G1061Afs*57 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.4561A>G p.T1521A | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- AKAP8 | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AMER3 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2
- AMZ1 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by muse, mutect2
- AOX1 | c.3700G>T p.D1234Y | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ASTN1 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ATG4C | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- BBS12 | c.2031G>T p.L677F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BCKDHB | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCOR | c.1372A>G p.M458V | Missense Mutation (SNP) | VAF 76/472 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- BICDL1 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- BRINP2 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BTNL9 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 66/464 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- C1D | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- C22orf42 | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 45/252 reads (18%) | called by muse, mutect2, varscan2
- CACNA1G | c.6116C>A p.S2039Y | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CANX | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAPN12 | c.467A>T p.D156V | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC13 | c.513+1G>A p.X171_splice | Splice Site (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- CCDC50 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDKAL1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- CEP43 | c.103-1G>A p.X35_splice | Splice Site (SNP) | VAF 21/237 reads (9%) | called by muse, mutect2
- CFAP74 | c.4390-2A>T p.X1464_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- CIITA | c.1455C>G p.S485R | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- CIT | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 43/253 reads (17%) | called by muse, mutect2, varscan2
- CLCNKA | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- COL15A1 | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- COL4A1 | c.4874A>G p.Y1625C | Missense Mutation (SNP) | VAF 54/401 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COMMD9 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CPED1 | c.65T>A p.L22* | Nonsense Mutation (SNP) | VAF 10/297 reads (3%) | called by muse, mutect2
- CT83 | c.10T>C p.Y4H | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CTAGE1 | c.399T>A p.N133K | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CTNND2 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DDIAS | c.2805T>G p.H935Q | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DMKN | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- DNAI3 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- ECEL1 | c.1006A>T p.S336C | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- EPB41L1 | c.2071del p.Q691Sfs*5 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | called by mutect2, pindel, varscan2
- EPPK1 | c.2378dup p.Y794Vfs*47 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- ERO1B | c.950T>A p.V317E | Missense Mutation (SNP) | VAF 52/428 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ESPL1 | c.3919C>A p.P1307T | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FAM47C | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- FAM71E2 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAT3 | c.3635T>A p.L1212* | Nonsense Mutation (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- FBP1 | c.955T>A p.L319M | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- FCGBP | c.7941G>T p.K2647N | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.076); called by muse, mutect2
- FGA | c.874G>C p.A292P | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGG | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FIP1L1 | c.326A>G p.Q109R | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- FOXI1 | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- FOXP2 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 85/570 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GAB1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GAL3ST3 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GAL3ST4 | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GARRE1 | c.1250G>C p.G417A | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GBGT1 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GEN1 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GIMAP4 | c.659G>C p.C220S | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.707); called by muse, mutect2
- GLI3 | c.474-1G>T p.X158_splice | Splice Site (SNP) | VAF 41/313 reads (13%) | called by muse, mutect2, varscan2
- GLRA2 | c.62A>C p.H21P | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8O | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by mutect2, varscan2
- GPR89A | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPX1 | c.461C>A p.P154Q | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM8 | c.1991C>A p.A664E | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HAUS6 | c.840A>T p.L280F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCLS1 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HHLA2 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HTRA4 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFT80 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 80/557 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- IGHV4-59 | c.216C>G p.Y72* | Nonsense Mutation (SNP) | VAF 37/402 reads (9%) | called by muse, mutect2, varscan2
- IGKV3D-11 | c.221G>T p.R74M | Missense Mutation (SNP) | VAF 52/597 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2
- IGLV3-16 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGSF11 | c.1280C>T p.A427V (on ENST00000393775 / NM_001015887.3; = p.A426V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IL18R1 | c.1227del p.Y410Ifs*10 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | called by pindel, varscan2
- IL37 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL3RA | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- IMMP2L | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- INA | c.1274A>T p.Y425F | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.347); called by muse, varscan2
- INTS5 | c.1979G>A p.R660K | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); called by muse, mutect2
- IQGAP3 | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2
- IRF8 | c.174+2T>A p.X58_splice | Splice Site (SNP) | VAF 24/255 reads (9%) | called by muse, mutect2
- ITGA2B | c.2423G>A p.G808E | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ITPA | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 81/404 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAKMIP3 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KCNAB2 | c.416-5C>A | Splice Region (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- KCNH1 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.431); called by muse, mutect2
- KCNJ3 | c.838T>G p.F280V | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KCNN2 | c.800A>T p.Y267F (on ENST00000264773; = p.Y479F on NM_021614.4) | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- KCNT1 | c.280C>A p.L94M (on ENST00000488444; = p.L113M on NM_020822.3) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF4A | c.1607A>T p.K536I | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KLHL4 | c.1109A>T p.Y370F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2
- KRT8 | c.1064A>T p.E355V | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- KRTAP4-3 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- LAYN | c.902C>A p.A301D (on ENST00000375615 / NM_001258390.1; = p.A293D on NM_178834.5) | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LCT | c.3075G>T p.Q1025H | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LHX5 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LILRB5 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- LRP1B | c.9654T>G p.I3218M | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRP1B | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 60/496 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAK | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAN2A1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 24/208 reads (12%) | called by muse, varscan2
- MKI67 | c.1837G>C p.V613L | Missense Mutation (SNP) | VAF 65/464 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MOCS1 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MRGPRD | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL47 | c.586A>G p.R196G | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- MUC16 | c.22674del p.A7559Qfs*43 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- MYBPC1 | c.362G>T p.R121L (on ENST00000550270 / NM_206820.2; = p.R146L on NM_002465.4) | Missense Mutation (SNP) | VAF 79/533 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MYBPC1 | c.1285G>T p.D429Y (on ENST00000550270 / NM_206820.2; = p.D454Y on NM_002465.4) | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MYH3 | c.4896C>A p.H1632Q | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MYO19 | c.716A>C p.Y239S | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOM2 | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NCAPD3 | c.4003G>T p.G1335W | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NCKAP5 | c.3688C>A p.Q1230K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NCOA6 | c.3836C>T p.T1279I | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NEFM | c.1559T>G p.V520G | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK9 | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NIT1 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- NOS1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- NOVA1 | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- NRXN2 | c.5021G>T p.R1674L | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NTPCR | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NUP205 | c.4420G>C p.G1474R | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR11L1 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2
- OR2G3 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2T3 | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- PALM3 | c.1552G>T p.E518* (on ENST00000340790; = p.E533* on NM_001145028.2) | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- PARD3B | c.916A>T p.I306F | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2
- PARD6B | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 35/343 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- PCK1 | c.1686T>G p.D562E | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZRN4 | c.1894G>T p.E632* (on ENST00000402685 / NM_001164595.2; = p.E374* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- PEG3 | c.4453G>T p.V1485L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGR | c.2752C>A p.P918T | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIBF1 | c.934A>C p.T312P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2
- PIGO | c.2234G>T p.R745L | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2
- PIK3CB | c.1631G>T p.R544M | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- POU5F1B | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PPIG | c.1760G>A p.S587N | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRUNE1 | c.179G>C p.R60P | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTCHD3 | c.1982T>A p.V661D | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RANBP2 | c.7976G>A p.C2659Y | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RASSF6 | c.331C>T p.P111S (on ENST00000342081 / NM_201431.2; = p.P79S on NM_177532.5) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RESP18 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- RFPL4AL1 | c.794G>A p.S265N | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFX8 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- RGL3 | c.780G>T p.L260F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- RGS18 | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); called by muse, mutect2
- RGS7BP | c.4A>C p.S2R | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.551); called by muse, mutect2
- ROR1 | c.1121G>T p.C374F | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.5152A>T p.I1718F | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.165); called by muse, mutect2
- RPP40 | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- SALL2 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SAMD9 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, varscan2
- SEC14L3 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- SEMA3D | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SGIP1 | c.776C>A p.T259N | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SIDT1 | c.643G>T p.V215F | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SIPA1L2 | c.2242A>G p.S748G | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC15A5 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 44/596 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SLC25A37 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC7A11 | c.1198A>T p.I400F | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SMG7 | c.3308G>C p.W1103S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SNN | c.82T>A p.L28M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SORCS2 | c.2568C>G p.N856K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SPEN | c.4283G>C p.R1428T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SPTA1 | c.3124C>A p.L1042I | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.067); called by muse, mutect2
- SRPK2 | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SRRM2 | c.1808G>T p.R603M | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SRRM2 | c.1809G>T p.R603S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- STAT4 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- STIM1 | c.1883C>G p.S628C | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- STK31 | c.2210A>T p.K737M | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STXBP6 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1L | c.1429C>A p.L477M | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.227); called by muse, mutect2
- TARM1 | c.765G>T p.M255I (on ENST00000616041 / NM_001330650.1; = p.M247I on NM_001135686.3) | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- THSD7B | c.4108C>T p.P1370S (on ENST00000272643; = p.P1368S on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- TLE3 | c.2111T>G p.L704R | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR7 | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- TMC2 | c.2083T>C p.Y695H | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNNT1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- TP53 | c.598_601dup p.L201* | Nonsense Mutation (INS) | VAF 30/206 reads (15%) | called by mutect2, pindel, varscan2
- TRBV28 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2
- TRPC5OS | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TTK | c.2408A>C p.K803T | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); called by muse, mutect2
- TTN | c.94712C>A p.S31571Y (on ENST00000591111; = p.S24147Y on NM_003319.4) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- UBAP2 | c.645G>T p.W215C | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBAP2 | c.644G>C p.W215S | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- UGT2B11 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- UMOD | c.1910T>A p.L637Q | Missense Mutation (SNP) | VAF 82/577 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- USH2A | c.14431T>C p.F4811L | Missense Mutation (SNP) | VAF 46/461 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- USH2A | c.10988C>G p.S3663C | Missense Mutation (SNP) | VAF 65/577 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- USP13 | c.2510A>T p.Y837F | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- USP28 | c.1878G>T p.W626C | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UTS2B | c.240+2T>A p.X80_splice | Splice Site (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- WDR25 | c.1523C>G p.A508G | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- XAB2 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- XKR3 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.025); called by muse, mutect2
- XKR9 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2
- YME1L1 | c.1233G>C p.M411I (on ENST00000326799 / NM_139312.3; = p.M354I on NM_014263.4) | Missense Mutation (SNP) | VAF 69/617 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZDHHC11 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2
- ZFHX4 | c.6479A>T p.Q2160L | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZIM2 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ZIM3 | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZNF280B | c.913A>C p.T305P | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF285 | c.1257G>T p.W419C | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- ZNF416 | c.1064A>C p.E355A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ZNF563 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF568 | c.830C>A p.P277Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZNF668 | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF732 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF774 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/118 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- ZNF90 | c.363T>G p.D121E | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.215); called by muse, mutect2
- ZSCAN5B | c.848A>T p.H283L | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZZEF1 | c.1667G>T p.R556M | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ADIPOQ | c.702C>T p.F234= | Silent (SNP) | VAF 47/266 reads (18%) | called by muse, mutect2, varscan2
- AGMO | c.1161C>T p.P387= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as rs376879419; called by muse, mutect2, varscan2
- AK9 | c.2556T>A p.A852= | Silent (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- AMER2 | c.591G>C p.L197= | Silent (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- AOC1 | c.2241C>A p.T747= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, varscan2
- ASS1 | c.696T>C p.P232= | Silent (SNP) | VAF 29/254 reads (11%) | catalogued as rs780610902; called by muse, mutect2, varscan2
- ATF7 | c.1098G>T p.L366= (on ENST00000548446 / NM_001366555.2; = p.L355= on NM_006856.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/410 reads (13%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.219G>A p.E73= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- CACNG6 | c.636C>T p.R212= (on ENST00000252729 / NM_145814.1; = p.R141= on NM_031897.2) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs376108604; called by muse, mutect2, varscan2
- CAPN1 | c.183C>T p.F61= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as rs765399122; called by muse, mutect2, varscan2
- CCDC22 | c.654G>T p.T218= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- CD19 | c.1536C>A p.P512= (on ENST00000324662 / NM_001178098.2; = p.P511= on NM_001770.6) | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV61189460; called by muse, mutect2, varscan2
- CIDEC | c.531C>T p.C177= | Silent (SNP) | VAF 29/272 reads (11%) | catalogued as COSV61061533; called by muse, mutect2, varscan2
- CPED1 | c.2259A>G p.Q753= | Silent (SNP) | VAF 70/456 reads (15%) | called by muse, varscan2
- CPNE5 | c.1509C>A p.G503= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- CTNNA2 | c.936C>T p.S312= | Silent (SNP) | VAF 33/272 reads (12%) | catalogued as rs779257738, COSV63547323, COSV63592832; called by muse, mutect2, varscan2
- DAPK1 | c.3972G>A p.G1324= | Silent (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.1398C>T p.H466= | Silent (SNP) | VAF 29/193 reads (15%) | catalogued as COSV101445877; called by muse, mutect2, varscan2
- DENND1A | c.960C>T p.F320= | Silent (SNP) | VAF 40/254 reads (16%) | catalogued as rs373730181; called by muse, mutect2, varscan2
- DOCK10 | c.4974T>A p.T1658= | Silent (SNP) | VAF 41/247 reads (17%) | called by muse, mutect2, varscan2
- EFCC1 | c.1062G>T p.G354= | Silent (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2, varscan2
- ESPNL | c.2325C>G p.G775= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs932129414; called by muse, mutect2
- ETV3L | c.636G>T p.R212= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- EVC | c.1531A>C p.R511= | Silent (SNP) | VAF 70/430 reads (16%) | called by muse, varscan2
- FAM20C | c.1191G>T p.L397= | Silent (SNP) | VAF 34/234 reads (15%) | called by muse, mutect2, varscan2
- FANCB | c.1659G>C p.T553= | Silent (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- FAT4 | c.8580C>A p.V2860= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- FCER1G | c.54C>A p.A18= | Silent (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- FLOT2 | c.564G>A p.R188= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs770539405; called by muse, mutect2, varscan2
- FOXA1 | c.1377C>T p.Y459= | Silent (SNP) | VAF 127/369 reads (34%) | called by muse, mutect2, varscan2
- GALNT17 | c.1530G>T p.L510= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- GPR55 | c.207T>C p.F69= | Silent (SNP) | VAF 47/371 reads (13%) | catalogued as rs1236361847; called by muse, mutect2, varscan2
- GRIN2B | c.3201C>A p.T1067= | Silent (SNP) | VAF 47/390 reads (12%) | catalogued as rs929166123, COSV101663248, COSV74207074; called by muse, mutect2, varscan2
- HEPACAM2 | c.579C>G p.S193= (on ENST00000394468 / NM_001039372.4; = p.S181= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/562 reads (17%) | called by muse, varscan2
- HOXD12 | c.645G>A p.A215= | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as rs762323732, COSV101184303, COSV66832768; called by muse, mutect2, varscan2
- IL37 | c.537C>A p.T179= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- ITIH2 | c.702C>T p.F234= | Silent (SNP) | VAF 73/352 reads (21%) | catalogued as rs148694864; called by muse, mutect2, varscan2
- KCTD1 | c.369G>A p.E123= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2
- KDELR2 | c.84C>T p.S28= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as rs1196079852, COSV99330604; called by muse, mutect2
- KIF21B | c.2595T>C p.S865= | Silent (SNP) | VAF 30/370 reads (8%) | called by muse, mutect2
- KMO | c.681T>G p.P227= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as COSV100844713; called by muse, mutect2, varscan2
- KRTAP19-2 | c.90C>T p.H30= | Silent (SNP) | VAF 58/404 reads (14%) | called by muse, mutect2, varscan2
- LIFR | c.2937G>A p.S979= | Silent (SNP) | VAF 25/224 reads (11%) | catalogued as rs201711670, COSV54700234, COSV99665426; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LY75 | c.3042G>A p.L1014= | Silent (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- MAB21L1 | c.672G>A p.S224= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs577985182, COSV100082155; called by muse, mutect2, varscan2
- MACF1 | c.14607A>T p.V4869= (on ENST00000372915; = p.V2802= on NM_012090.5) | Silent (SNP) | VAF 28/181 reads (15%) | called by muse, mutect2, varscan2
- MEX3D | c.1824G>T p.V608= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- MTMR12 | c.648A>G p.E216= | Silent (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- MYO1B | c.1872C>T p.N624= | Silent (SNP) | VAF 46/381 reads (12%) | catalogued as rs367794082; called by muse, mutect2, varscan2
- NELFCD | c.585G>A p.G195= (on ENST00000602795; = p.G177= on NM_198976.4) | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- NLRX1 | c.2334G>A p.Q778= | Silent (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1497G>T p.T499= | Silent (SNP) | VAF 39/405 reads (10%) | catalogued as COSV56922488; called by muse, mutect2, varscan2
- NRBP1 | c.1011G>T p.A337= | Silent (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- NSUN6 | c.984A>C p.G328= | Silent (SNP) | VAF 39/220 reads (18%) | called by muse, mutect2, varscan2
- NTRK1 | c.132C>T p.G44= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs1370714107; called by muse, mutect2
- OR4C46 | c.636G>T p.L212= | Silent (SNP) | VAF 18/372 reads (5%) | catalogued as COSV100060738, COSV100060978; called by muse, mutect2
- OR6C3 | c.294C>A p.L98= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- PCLO | c.5847G>A p.G1949= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs1223703765, COSV100426380; called by muse, mutect2, varscan2
- PDE3A | c.240G>T p.L80= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- PENK | c.426G>A p.K142= | Silent (SNP) | VAF 33/191 reads (17%) | catalogued as rs757143992; called by muse, mutect2, varscan2
- PITRM1 | c.1395G>A p.L465= | Silent (SNP) | VAF 63/298 reads (21%) | called by muse, varscan2
- PLAGL1 | c.957A>G p.K319= | Silent (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1014C>A p.V338= | Silent (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- PLXND1 | c.1155G>C p.P385= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs1343826171; called by muse, mutect2, varscan2
- POLR3E | c.267C>A p.T89= | Silent (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- POU6F2 | c.384G>A p.A128= | Silent (SNP) | VAF 45/419 reads (11%) | catalogued as rs1283569251, COSV68874521; called by muse, mutect2, varscan2
- PRR23C | c.570G>T p.R190= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV68827358; called by muse, mutect2, varscan2
- PSKH2 | c.540T>A p.T180= | Silent (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- PTPRM | c.4287C>T p.P1429= | Silent (SNP) | VAF 19/129 reads (15%) | called by muse, mutect2, varscan2
- PXDN | c.3051G>A p.E1017= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs1313872258, COSV53247166; called by muse, mutect2
- RAB27A | c.651G>A p.G217= | Silent (SNP) | VAF 30/387 reads (8%) | called by muse, mutect2
- RFPL1 | c.510G>T p.L170= | Silent (SNP) | VAF 50/343 reads (15%) | called by muse, mutect2, varscan2
- RGN | c.105T>C p.P35= | Silent (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- SAFB2 | c.2562A>G p.L854= | Silent (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- SERPINA9 | c.276C>A p.T92= | Silent (SNP) | VAF 76/389 reads (20%) | called by muse, mutect2, varscan2
- SLC12A9 | c.1605G>T p.L535= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- SPANXB1 | c.45C>T p.P15= | Silent (SNP) | VAF 92/1558 reads (6%) | called by muse, mutect2
- TAGAP | c.2007G>A p.Q669= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs200804434, COSV57850529, COSV57850786; called by muse, mutect2, varscan2
- TECTA | c.1026C>A p.G342= | Silent (SNP) | VAF 51/327 reads (16%) | called by muse, mutect2, varscan2
- TECTA | c.6231G>T p.V2077= | Silent (SNP) | VAF 48/368 reads (13%) | called by muse, mutect2, varscan2
- XKR7 | c.1362C>T p.I454= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs1429004472; called by muse, mutect2, varscan2
- ZNF280C | c.162A>T p.S54= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- ZNF438 | c.2232A>G p.E744= | Silent (SNP) | VAF 104/520 reads (20%) | called by muse, mutect2, varscan2
- ABCA12 | c.*48G>A | 3'UTR (SNP) | VAF 28/182 reads (15%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793783 A>T | 3'Flank (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3698G>T | Intron (SNP) | VAF 34/200 reads (17%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3902G>A | Intron (SNP) | VAF 27/249 reads (11%) | called by muse, mutect2, varscan2
- ARMT1 | c.-52G>C | 5'UTR (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- ASH1L | c.7905+203C>G | Intron (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700787 C>A | 3'Flank (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- C19orf12 | chr19:29700788 C>A | 3'Flank (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- CASP4 | c.-42G>A | 5'UTR (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- CCDC39 | n.624G>T | RNA (SNP) | VAF 40/258 reads (16%) | called by muse, mutect2, varscan2
- CDC123 | c.*6G>A | 3'UTR (SNP) | VAF 50/189 reads (26%) | catalogued as rs753146786, COSV99826696; called by muse, mutect2, varscan2
- CPNE7 | c.1764+292G>A | Intron (SNP) | VAF 39/215 reads (18%) | called by muse, mutect2, varscan2
- CTNS | c.140+19C>A | Intron (SNP) | VAF 77/318 reads (24%) | called by muse, mutect2, varscan2
- DAO | chr12:108879844 G>T | 5'Flank (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- EMD | c.-30G>T | 5'UTR (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- EPS8L3 | c.*32C>A | 3'UTR (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- FAM135B | c.157+1847C>A | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- FHL2 | chr2:105399331 G>A | 5'Flank (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- FRAS1 | c.2422+49G>C | Intron (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- GANC | c.201+2524G>A | Intron (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- GMDS | c.103-51213C>T | Intron (SNP) | VAF 17/321 reads (5%) | called by muse, mutect2
- GNB5 | c.864-469A>G | Intron (SNP) | VAF 42/224 reads (19%) | catalogued as rs1033871259; called by muse, mutect2, varscan2
- GSDMD | c.-5+377A>G | Intron (SNP) | VAF 10/93 reads (11%) | catalogued as rs1202133278; called by muse, mutect2
- HRAS | c.*5+23C>T | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- HSP90AB3P | n.523T>A | RNA (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- IDI1 | c.140+31A>G | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2
- IFT122 | c.273-326C>A | Intron (SNP) | VAF 49/378 reads (13%) | called by muse, mutect2, varscan2
- KRT8P11 | n.1009G>T | RNA (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- LINC01387 | n.95A>T | RNA (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- MAP2 | c.455-1816G>T | Intron (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- MMAB | c.348+29G>T | Intron (SNP) | VAF 34/356 reads (10%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:20340025 G>C | 5'Flank (SNP) | VAF 26/170 reads (15%) | called by mutect2, varscan2
- NCALD | c.*161G>C | 3'UTR (SNP) | VAF 32/189 reads (17%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1542G>C | RNA (SNP) | VAF 32/208 reads (15%) | called by muse, varscan2
- NOC2LP2 | n.1465A>T | RNA (SNP) | VAF 37/317 reads (12%) | called by muse, varscan2
- PAH | c.-31A>T | 5'UTR (SNP) | VAF 45/350 reads (13%) | called by muse, mutect2, varscan2
- PLAAT3 | c.-6G>A | 5'UTR (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- PRSS36 | c.73+13G>A | Intron (SNP) | VAF 26/207 reads (13%) | catalogued as rs959237069; called by muse, mutect2, varscan2
- RFX3 | c.1202+39G>T | Intron (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159761 T>A | 5'Flank (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2
- RNF217-AS1 | n.392T>G | RNA (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- RNU6-1191P | chr16:81108646 G>T | 5'Flank (SNP) | VAF 18/176 reads (10%) | catalogued as rs1317134839; called by muse, mutect2, varscan2
- S1PR1 | c.*8A>T | 3'UTR (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.12C>A | RNA (SNP) | VAF 26/190 reads (14%) | called by muse, varscan2
- SIGLEC17P | n.13C>A | RNA (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- SLC16A1 | c.218-27A>G | Intron (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- SLC25A48 | c.679+11C>G | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- SSX6P | n.325G>A | RNA (SNP) | VAF 40/226 reads (18%) | catalogued as rs781914136; called by muse, mutect2, varscan2
- STAG3L4 | n.419C>A | RNA (SNP) | VAF 18/308 reads (6%) | called by muse, mutect2
- TAF10 | c.*1739G>A | 3'UTR (SNP) | VAF 20/98 reads (20%) | catalogued as rs747363575; called by muse, mutect2, varscan2
- TMEM135 | c.-89C>G | 5'UTR (SNP) | VAF 8/41 reads (20%) | catalogued as rs758945256; called by muse, mutect2, varscan2
- TMTC3 | c.1199+233C>A | Intron (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- TUBB7P | n.1276G>T | RNA (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2
- UTRN | c.7480-18131G>T | Intron (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- YTHDF3 | c.*3G>A | 3'UTR (SNP) | VAF 12/144 reads (8%) | catalogued as rs755196711, COSV72773760; called by muse, mutect2
- ZNF849P | n.253T>C | RNA (SNP) | VAF 6/47 reads (13%) | catalogued as rs1387458104; called by muse, mutect2, varscan2
